TCGA case TCGA-IE-A3OV — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: ABS - IUPUI. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/24d08a93-d078-407b-8d93-5f7a099821eb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 42 years; Vital status: Dead; Days to death: 2,448 days (6.7 years).

Diagnoses (8)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 42.7 years (15,607 days); Year of diagnosis: 2004; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Contiguous organ invaded: Kidney; Sites of involvement: Lung, NOS / Kidney, NOS; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Tumor burden: 5.5.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 1; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 5; Tumor length measurement: 10.5; Tumor width measurement: 4.8.
   Pathology details: Measurement type: Pathologic; Tumor burden: 10.5.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 5.5; Tumor length measurement: 2.5; Tumor width measurement: 5.3.
2. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 44.1 years (16,097 days); Days to diagnosis: 490 days (1.3 years); Prior treatment: Yes.
3. Recurrence of diagnosis 1 (Leiomyosarcoma, NOS), site: Lower limb, NOS. Age at diagnosis: 46.5 years (16,978 days); Days to diagnosis: 1,371 days (3.8 years); Prior treatment: Yes; Tumor focality: Unifocal.
4. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Kidney, NOS. Age at diagnosis: 47.6 years (17,392 days); Days to diagnosis: 1,785 days (4.9 years); Prior treatment: Yes; Tumor focality: Multifocal.
5. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Head, face or neck, NOS. Age at diagnosis: 48.7 years (17,804 days); Days to diagnosis: 2,197 days (6.0 years); Prior treatment: Yes; Tumor focality: Unifocal.
6. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Other ill-defined sites. Age at diagnosis: 48.7 years (17,804 days); Days to diagnosis: 2,197 days (6.0 years); Prior treatment: Yes; Tumor focality: Multifocal.
7. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Liver. Age at diagnosis: 49.4 years (18,042 days); Days to diagnosis: 2,435 days (6.7 years); Prior treatment: Yes; Tumor focality: Unifocal.
8. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS). Age at diagnosis: 49.4 years (18,042 days); Days to diagnosis: 2,435 days (6.7 years); Prior treatment: Yes; Tumor focality: Multifocal.

Follow-up (7 entries)
- Day 490 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 490 days (1.3 years).
- Day 1,371 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lower limb, NOS; Days to recurrence: 1,371 days (3.8 years).
- Day 1,785 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Kidney, NOS; Days to progression: 1,785 days (4.9 years).
- Day 2,197 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Other ill-defined sites; Days to progression: 2,197 days (6.0 years).
- Day 2,197 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Head, face or neck, NOS; Days to progression: 2,197 days (6.0 years).
- Day 2,435 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 2,435 days (6.7 years).
- Days to follow up: 2,448 days (6.7 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 15.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IE-A3OV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 250 mg.
  Slide TCGA-IE-A3OV-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-IE-A3OV-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IE-A3OV-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 330 mg.
  Slide TCGA-IE-A3OV-11A-02-TSB: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Poorly differentiated or pleomorphic or epithelioid leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative; Tumor total necrosis: <10% (focal necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: Yes; Metastasis site: Lung; Contiguous organ invaded: Yes.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Thigh/knee.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic depth: 5.0.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 102; Pharmaceutical therapy drug name: Dacarbazine (DTIC); Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 102; Pharmaceutical therapy drug name: Adriamycin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 778; Days from index date to pharmaceutical treatment ended: 836; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 4: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 787; Days from index date to pharmaceutical treatment ended: 836; Pharmaceutical therapy drug name: Taxotere; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 5: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 1411; Days from index date to pharmaceutical treatment ended: 1594; Pharmaceutical therapy drug name: ET-743; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 6: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 1609; Days from index date to pharmaceutical treatment ended: 1660; Pharmaceutical therapy drug name: AP-23573 (ARIAD); Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 7: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 1834; Days from index date to pharmaceutical treatment ended: 1918; Pharmaceutical therapy drug name: EZN-2968; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 7, Therapy types: Pharmaceutical therapy type: Targeted Molecular therapy.
- Drug treatment 8: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 1973; Days from index date to pharmaceutical treatment ended: 2037; Pharmaceutical therapy drug name: Enoticumab; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 8, Therapy types: Pharmaceutical therapy type: Immunotherapy.
- Drug treatment 9: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 2073; Days from index date to pharmaceutical treatment ended: 2093; Pharmaceutical therapy drug name: Threshold-302; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 10: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 2232; Days from index date to pharmaceutical treatment ended: 2293; Pharmaceutical therapy drug name: Alimta; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Days from index date to radiation therapy started: 2438; Days from index date to radiation therapy ended: 2438; Radiation therapy type: External; Radiation total dose: 400; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 1; Radiation therapy site: Distant Recurrence; Radiation therapy ongoing indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,448 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,448 days; disease-free interval: event (new tumor event after initially disease-free), 490 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 490 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IE-A3OV-01A-11D-A227-01): tumor purity 0.78, ploidy 3.1, whole-genome doublings 1.
